Surgical pathology report (de-identified scan), TCGA case TCGA-60-2712, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2712-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. 4R RIGHT DISTAL PARATRACHEAL
B. 4L LEFT DISTAL PARATRACHEAL
C. ADDITIONAL LOW 4R RIGHT DISTAL PARATRACHEAL
D. LEVEL 7 SUBCARINAL
E. 2R RIGHT PROXIMAL PARATRACHEAL
F. 2L LEFT PROXIMAL PARATRACHEAL
G. FIFTH RIB
H. LEVEL 5 LYMPH NODE
I. LEFT UPPER LOBE
J. 11L LYMPH NODE
K. LEVEL 6 LYMPH NODE
L. LEVEL 9 LYMPH NODE

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Left upper lobe mass

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA, FSB, FSC, FSD, FSE, FSF: Negative for tumor.

FS11: Bronchial margin: Negative for tumor.

FS12: Tumor: Poorly differentiated squamous cell carcinoma.

[page 2 of 4]
GROSS DESCRIPTION:

A. 4R RIGHT DISTAL PARATRACHEAL

Received fresh is one fragment of tan-black soft tissue measuring 0.3 cm. Submitted in toto for frozen section.

B. 4L LEFT DISTAL PARATRACHEAL

Received fresh are multiple fragments of tan-black tissue measuring 0.5 cm in aggregate. Submitted in toto for frozen section.

C. ADDITIONAL LOW 4R RIGHT DISTAL PARATRACHEAL

Received fresh are multiple fragments of tan-black soft tissue measuring 1.5 x 0.7 x 0.4 cm. Submitted in toto for frozen section.

D. LEVEL 7 SUBCARINAL

Received fresh are multiple fragments of tan-black soft tissue measuring 1 x 0.8 x 0.3 cm in aggregate. Submitted in toto for frozen section.

E. 2R RIGHT PROXIMAL PARATRACHEAL

Received fresh are multiple fragments of tan-black soft tissue measuring 1.2 x 0.9 x 0.3 cm. They are submitted in toto for frozen section.

F. 2L LEFT PROXIMAL PARATRACHEAL

Received fresh is one fragment of tan-black soft tissue measuring 0.3 cm in diameter and submitted in toto for frozen section.

G. FIFTH RIB

Received in formalin is a portion of rib measuring 2 x 1 x 0.8 cm. The outer surface is tan-pink and irregular. Sections are submitted after decalcification.

H. LEVEL 5 LYMPH NODE

Received in formalin is one lymph node measuring 2 x 1.5 x 0.5 cm. It is bisected to reveal black to pink homogenous cut surface. It is submitted in toto in one cassette.

I. LUNG LEFT UPPER LOBE,LOBECTOMY:

Received in fresh state is a resected upper lobe of left lung with total dimensions of 15x14x4 cm. in the upper half of the specimen located .4 cm. from the nearest bronchial margin. There is a firm ovoid to round palpable mass which on section has a tan cream yellow tan-white tumor with central areas of necrosis. The tumor measures 8x7x4 cm. The overlying pleura is retracted and inked blue. At the hilum in line with the bronchus and protruding from the long is a presumptive enlarged matted lymph node with tumor partly displacing one hilar blood vessel. Remainder of the specimen shows congestion with atelectatic change. Multiple sections are submitted and labeled as follows: portion of tissue for tissue procurement and photograph of specimen is a well defined round to oval tan-yellow firm tumor mass with central tumor necrosis measuring 8 x 7 x 4 cm.

Sections are submitted as follows:

FSI1: bronchial margin

FSI2: sections from the tumor for frozen section

I3-I7: sections from the tumor

I8: sections from the mass and lymph nodes adjacent to the tumor

I9-I10: two sections from the tumor

[page 3 of 4]
[REDACTED]

I11-I12: section of lymph node paratracheal
I13-I15: sections from the non-neoplastic lung tissue

J. 11L LYMPH NODE

Received in formalin is one irregular lymph node measuring 2 x 1.5 x 1 cm. It is trisected to reveal black and pink homogenous cut surface. It is submitted in toto in one cassette.

K. LEVEL 6 LYMPH NODE

Received in formalin is one lymph node measuring 1 x 0.8 x 0.5 cm. It is bisected to reveal black homogenous cut surface. It is submitted in toto in one cassette.

L. LEVEL 9 LYMPH NODE

Received in formalin is one lymph node measuring 0.8 x 0.7 x 0.5 cm. It is bisected to reveal a black cut surface. It is submitted in toto in one cassette.

[REDACTED]

DIAGNOSIS:

A. 4 RIGHT DISTAL PARATRACHEAL LYMPH NODE:

- ONE LYMPH NODE – NEGATIVE FOR TUMOR (0/1).

B. 4 LEFT DISTAL PARATRACHEAL LYMPH NODE:

- ONE LYMPH NODE – NEGATIVE FOR TUMOR (0/1).

C. ADDITIONAL LOW 4 RIGHT DISTAL PARATRACHEAL:

- ONE LYMPH NODE – NEGATIVE FOR TUMOR (0/1).

D. LEVEL 7 SUBCARINAL LYMPH NODE:

- ONE LYMPH NODE – NEGATIVE FOR TUMOR (0/1).

E. 2 RIGHT PROXIMAL PARATRACHEAL LYMPH NODE:

- ONE LYMPH NODE – NEGATIVE FOR TUMOR (0/1).

F. 2 LEFT PROXIMAL PARATRACHEAL LYMPH NODE:

- ONE LYMPH NODE – NEGATIVE FOR TUMOR (0/1).

G. FIFTH RIB:

- PORTION OF RIB BONE – NEGATIVE FOR TUMOR.

H. LEVEL 5 LYMPH NODE:

- ONE LYMPH NODE – NEGATIVE FOR TUMOR (0/1).

I. LUNG, LEFT UPPER LOBE, LOBECTOMY SPECIMEN:

- SQUAMOUS CELL CARCINOMA, MODERATE TO POORLY
DIFFERENTIATED OF UPPER LOBE OF LEFT LUNG WITH METATASIS
TO ONE OUT OF TWENTY-FIVE PERIBRONCHIAL LYMPH NODES (1/25).

- SIZE OF TUMOR: 8x7x4 CM.

- BRONCHIAL MARGINS OF RESECTION – NEGATIVE FOR TUMOR.

- CONGESTION AND FOCAL ATELECTATIC CHANGE OF LUNG.

J. 11 LEFT LYMPH NODE:

- ONE LYMPH NODE – NEGATIVE TUMOR (0/1).

K. LEVEL 6 LYMPH NODE:

[REDACTED]

[page 4 of 4]
-
- ONE LYMPH NODE – NEGATIVE FOR TUMOR (0/1).
L. LEVEL 9 LYMPH NODE:
- ONE LYMPH NODE – NEGATIVE FOR TUMOR (0/1).

LUNG NEOPLASM TEMPLATE

Surgical procedure:	Lobectomy
Tumor location:	Central - LUL
Tumor size:	8 x 7 x 4 cm
Tumor type:	Squamous cell carcinoma
Histologic grade:	G2-G3
Angiolymphatic invasion:	Absent
Bronchial margin:	Negative
Visceral pleural involvement:	Absent
Satellite tumor(s):	No
Lymph node involvement:	
N1: Ipsilateral Hilar (Level 10) and/or Peribronchial (Levels 11-14)	Positive (1/26)
N2: Ipsilateral Mediastinal (Levels 1-9) and/or subcarinal	Negative (0/4)
N3: Contralateral mediastinal/hilar Scalene or supraclavicular	Negative (0/5)
Non-neoplastic lung:	
Pathologic stage:	pT2 N1 Mx

Source: NCI Genomic Data Commons file 4456d133-7607-49d9-a263-a19d5b347f01 (TCGA-60-2712.DC936761-8BC0-4F4D-BA51-D6C9C0009C3B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).